Somatic mutation profile of tumor specimen TARGET-30-PATPET-01A (aliquot TARGET-30-PATPET-01A-01D) from TARGET case TARGET-30-PATPET, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,520 days).
Specimen TARGET-30-PATPET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0846a2ed-a277-4b92-ac19-a5e00396521c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATPET-10A (Blood Derived Normal), aliquot TARGET-30-PATPET-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8783b43f-d1bc-4e0d-8e99-b8ccc2f0a98b

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DACH1 | chr13:71439182 A>T | 3'Flank (SNP) | VAF 44/128 reads (34%) | catalogued as COSV57525056; called by muse, mutect2, varscan2
